Somatic mutation profile of tumor specimen ALCH-AEZ0-TTP1-A (aliquot ALCH-AEZ0-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEZ0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.5 years (27,208 days).
Specimen ALCH-AEZ0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a65d698-48e2-412f-ab8a-3314e79026f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEZ0-NB1-A (Blood Derived Normal), aliquot ALCH-AEZ0-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcf08318-22ff-4bb8-bcfb-a872aa6986c3

The open-access MAF lists 87 somatic variants for this specimen: 57 protein-altering or splice-affecting, 20 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 20, Intron 6, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 2, 3'UTR 1, Nonstop Mutation 1, 5'UTR 1, RNA 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 133/824 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.515T>G p.V172G | Missense Mutation (SNP) | VAF 41/272 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1131691021, COSV52683521, COSV52729554, COSV52811339, COSV52993405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.8020A>T p.K2674* | Nonsense Mutation (SNP) | VAF 34/692 reads (5%) | catalogued as COSV52170383; called by muse, mutect2
- ARMC6 | c.95C>G p.A32G (on ENST00000392336; = p.A7G on NM_033415.4) | Missense Mutation (SNP) | VAF 96/554 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs146096868; called by muse, mutect2, varscan2
- ATM | c.8861A>G p.Y2954C | Missense Mutation (SNP) | VAF 89/565 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767507047, COSV53730237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT10 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147379946, COSV59394552; called by muse, mutect2
- FAT4 | c.13379C>T p.T4460M | Missense Mutation (SNP) | VAF 51/422 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs774990923, COSV58680010, COSV58680473; called by muse, mutect2, varscan2
- HS6ST2 | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); catalogued as COSV63715522; called by muse, mutect2, varscan2
- KNG1 | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs777284943; called by muse, mutect2
- NEFM | c.872G>T p.W291L | Missense Mutation (SNP) | VAF 73/563 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs1187761822; called by muse, mutect2, varscan2
- NR1D1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 31/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52840355; called by muse, mutect2
- OGDHL | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1331747020, COSV65104090; called by muse, mutect2, varscan2
- OGFOD3 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs780739143; called by muse, mutect2
- PLCH2 | c.1408-1G>A p.X470_splice | Splice Site (SNP) | VAF 18/120 reads (15%) | catalogued as rs1465372331; called by muse, mutect2, varscan2
- PTPRZ1 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 31/303 reads (10%) | catalogued as rs771283585, COSV66436171, COSV66436709; called by muse, mutect2
- RTL9 | c.3811C>T p.R1271W | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1456180070, COSV71825500; called by muse, mutect2
- SLC9C2 | c.1106G>A p.W369* | Nonsense Mutation (SNP) | VAF 27/680 reads (4%) | catalogued as rs986965280; called by muse, mutect2
- UGT2A1 | c.1084+1G>A p.X362_splice | Splice Site (SNP) | VAF 21/723 reads (3%) | catalogued as rs1337562356; called by muse, mutect2
- ANKRD11 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- APBA3 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.108); called by muse, mutect2
- APRT | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP6V0A4 | c.2209A>T p.N737Y | Missense Mutation (SNP) | VAF 63/603 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP251 | c.2403G>C p.W801C | Missense Mutation (SNP) | VAF 16/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CMTM8 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNPY4 | c.47T>G p.V16G | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CREBZF | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CRTC3 | c.637A>G p.K213E | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.158); called by muse, mutect2
- DYNC2I1 | c.2728G>C p.V910L | Missense Mutation (SNP) | VAF 50/415 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- FLRT3 | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 67/507 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FRMPD3 | c.4424C>G p.S1475C | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIG1 | c.2615A>G p.N872S | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2
- LRRC53 | c.1001G>C p.R334T | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- MRPS22 | c.923C>T p.P308L (on ENST00000310776 / NM_001363893.1; = p.P309L on NM_020191.4) | Missense Mutation (SNP) | VAF 29/1054 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MST1 | c.1944C>G p.I648M | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- MYBL2 | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NFKBIA | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 44/627 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.499); called by muse, mutect2
- NOTCH2 | c.1513A>T p.N505Y | Missense Mutation (SNP) | VAF 44/912 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA4 | c.1078G>C p.A360P | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDIA2 | c.822G>T p.R274S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PKHD1 | c.2039A>T p.N680I | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2
- RBM10 | c.2170_2171del p.P724Sfs*13 | Frame Shift Del (DEL) | VAF 25/187 reads (13%) | called by mutect2, pindel, varscan2
- RIPOR2 | c.3205T>A p.*1069Kext*36 | Nonstop Mutation (SNP) | VAF 20/600 reads (3%) | called by muse, mutect2
- RUBCN | c.1684+1G>A p.X562_splice | Splice Site (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- SAMD10 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCFD1 | c.1735A>T p.S579C | Missense Mutation (SNP) | VAF 99/635 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SH3GL2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SHC2 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, varscan2
- SLC9C2 | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 28/680 reads (4%) | called by muse, mutect2
- STK26 | c.537dup p.V180Cfs*10 | Frame Shift Ins (INS) | VAF 62/391 reads (16%) | called by pindel, varscan2
- TSPAN19 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 19/436 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2
- TUBAL3 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- TYSND1 | c.1332_1342del p.F444Lfs*58 | Frame Shift Del (DEL) | VAF 9/107 reads (8%) | called by mutect2, pindel
- ZBTB1 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB14 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF549 | c.991C>T p.P331S (on ENST00000376233 / NM_001199295.2; = p.P318S on NM_153263.2) | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZNF630 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 15/301 reads (5%) | called by muse, mutect2
- ZXDA | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ACSL6 | c.696A>G p.E232= (on ENST00000379240; = p.E257= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/277 reads (18%) | called by muse, mutect2, varscan2
- ADAM22 | c.1314T>A p.P438= | Silent (SNP) | VAF 54/352 reads (15%) | called by muse, mutect2, varscan2
- ALG3 | c.907C>T p.L303= | Silent (SNP) | VAF 47/204 reads (23%) | called by muse, mutect2, varscan2
- DPP6 | c.1335G>A p.K445= (on ENST00000377770 / NM_001364500.2; = p.K383= on NM_001936.5) | Silent (SNP) | VAF 14/381 reads (4%) | called by muse, mutect2
- EIF2S3B | c.99C>T p.H33= | Silent (SNP) | VAF 122/989 reads (12%) | catalogued as rs2230569; called by muse, mutect2, varscan2
- EMC3 | c.108C>T p.I36= | Silent (SNP) | VAF 16/383 reads (4%) | called by muse, mutect2
- FGG | c.393A>T p.S131= | Silent (SNP) | VAF 43/464 reads (9%) | called by muse, mutect2
- KIAA1755 | c.390A>T p.T130= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- KIF26A | c.4992G>A p.R1664= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs1176218762; called by muse, mutect2, varscan2
- LEO1 | c.27G>C p.G9= | Silent (SNP) | VAF 14/389 reads (4%) | called by muse, mutect2
- LRRC24 | c.981C>T p.S327= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- MAPK9 | c.66C>G p.V22= | Silent (SNP) | VAF 12/418 reads (3%) | called by muse, mutect2
- OR1E2 | c.345T>G p.L115= | Silent (SNP) | VAF 24/432 reads (6%) | called by muse, mutect2
- PGLYRP4 | c.984C>T p.D328= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as rs761010131; called by muse, mutect2
- PHLDB1 | c.2577G>T p.R859= | Silent (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2
- PLIN4 | c.2763C>T p.V921= (on ENST00000301286; = p.V936= on NM_001367868.2) | Silent (SNP) | VAF 44/254 reads (17%) | called by muse, mutect2, varscan2
- SESN2 | c.237G>T p.L79= | Silent (SNP) | VAF 19/501 reads (4%) | called by muse, mutect2
- SLC4A1 | c.1266C>T p.T422= | Silent (SNP) | VAF 34/544 reads (6%) | catalogued as rs1366346691; called by muse, mutect2
- UGT2A2 | c.466T>C p.L156= | Silent (SNP) | VAF 43/420 reads (10%) | called by muse, mutect2
- USH2A | c.12519G>C p.L4173= | Silent (SNP) | VAF 15/351 reads (4%) | catalogued as COSV100230841, COSV56361121; called by muse, mutect2
- AL353804.7 | chrX:73850721 ins G | 3'Flank (INS) | VAF 12/80 reads (15%) | catalogued as rs1569512871; called by pindel, varscan2
- BOLL | c.352+1626G>C | Intron (SNP) | VAF 17/239 reads (7%) | called by muse, mutect2
- CDKL5 | c.2713+46C>T | Intron (SNP) | VAF 34/234 reads (15%) | called by muse, mutect2, varscan2
- FBXW11 | c.45+9418C>T | Intron (SNP) | VAF 56/550 reads (10%) | called by muse, mutect2, varscan2
- FO393400.1 | c.-8C>T | 5'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2
- LAMC2 | c.*43A>G | 3'UTR (SNP) | VAF 20/401 reads (5%) | called by muse, mutect2
- TBC1D9B | c.2791+128A>T | Intron (SNP) | VAF 34/241 reads (14%) | catalogued as rs1388645422; called by muse, mutect2, varscan2
- TSPEAR | c.1566+3165C>T | Intron (SNP) | VAF 14/102 reads (14%) | catalogued as rs1001262562; called by muse, mutect2
- XIST | n.11289C>A | RNA (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- ZNF829 | c.-85+128G>A | Intron (SNP) | VAF 14/367 reads (4%) | called by muse, mutect2
